Gene-level copy-number profile of tumor specimen TCGA-AR-A0TR-01A from TCGA case TCGA-AR-A0TR, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 69.0 years (25,190 days).
Specimen TCGA-AR-A0TR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.0d98d3ff-375a-4f82-ba8e-734a8a8fc17e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AR-A0TR-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d23e3b45-f464-42a7-898f-788c7f4cb9f9

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 34; copy number 2: 4,692; copy number 3: 12,743; copy number 4: 24,889; copy number 5: 14,853; copy number 6: 2,604.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AR-A0TR-01A-11D-A087-01): tumor purity 0.75, ploidy 4, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 34 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:167,767,083–169,297,959, 34 genes: AL009178.1, LINC01558, AL009178.2, AL009178.3, AFDN-DT, AFDN, HGC6.3, KIF25-AS1, KIF25, FRMD1, AL611929.1, AL606970.5, AL606970.4, AL606970.2, AL606970.3, CTAGE13P, DACT2, AL606970.1, AL138918.1, SMOC2, AL136099.1, AL513210.2, AL513210.1, AL109924.4, AL109924.3, AL109924.1, AL109924.2, AL136129.1, LINC01615, LINC02544, BX322234.1, THBS2, BX322234.2, VTA1P1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
